Somatic mutation profile of tumor specimen TCGA-C5-A2LS-01A (aliquot TCGA-C5-A2LS-01A-22D-A22X-09) from TCGA case TCGA-C5-A2LS, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB2; Tumor grade: G1; Age at diagnosis: 37.9 years (13,857 days).
Specimen TCGA-C5-A2LS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 40e38ff3-4f9b-4bcb-8f9f-888b4e3d0876.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-C5-A2LS-10A (Blood Derived Normal), aliquot TCGA-C5-A2LS-10A-01D-A22X-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c0b1782b-536d-4cfb-b9e4-0fb70c7d8053

The open-access MAF lists 57 somatic variants for this specimen: 36 protein-altering or splice-affecting, 20 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 20, Nonsense Mutation 3, Splice Site 2, RNA 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 64/100 reads (64%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- AHNAK2 | c.1568C>T p.A523V | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs774783031, COSV60910028; called by muse, mutect2, varscan2
- APLP2 | c.1690C>A p.L564I | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.704); catalogued as COSV53845164; called by muse, mutect2, varscan2
- ASXL1 | c.3991C>T p.P1331S | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.121); catalogued as COSV60124063; called by muse, mutect2, varscan2
- CNR2 | c.482C>T p.S161L | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.314); catalogued as COSV65692708; called by muse, mutect2, varscan2
- COLGALT2 | c.373G>T p.E125* | Nonsense Mutation (SNP) | VAF 39/129 reads (30%) | catalogued as COSV62731631; called by muse, mutect2, varscan2
- FAM162B | c.317G>A p.R106Q | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); catalogued as rs541992567, COSV63920440, COSV63920880; called by muse, mutect2, varscan2
- FBRS | c.862C>T p.R288W (on ENST00000287468; = p.R808W on NM_001105079.3) | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as rs771228797, COSV54919043; called by muse, mutect2, varscan2
- FMO5 | c.926A>T p.E309V | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.257); catalogued as COSV54211220; called by muse, mutect2, varscan2
- GNAT3 | c.542C>T p.T181M | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs775635099, COSV68069429; called by muse, mutect2, varscan2
- GPR139 | c.463A>G p.T155A | Missense Mutation (SNP) | VAF 31/131 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV58505394; called by muse, mutect2, varscan2
- GUCY1A2 | c.325C>T p.L109F | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV56504296; called by muse, mutect2, varscan2
- HFM1 | c.271C>T p.Q91* | Nonsense Mutation (SNP) | VAF 26/80 reads (33%) | catalogued as COSV54038496; called by muse, mutect2, varscan2
- IFNG | c.31C>G p.Q11E | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.732); catalogued as COSV57492161; called by muse, mutect2, varscan2
- KCNT2 | c.2276+1G>A p.X759_splice | Splice Site (SNP) | VAF 17/76 reads (22%) | catalogued as rs773222585, COSV54074419; called by muse, mutect2, varscan2
- KHDC1 | c.709C>T p.P237S (on ENST00000370384 / NM_001251874.2; = p.P164S on NM_030568.5) | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV57616320; called by muse, mutect2, varscan2
- KIF4A | c.2329G>T p.D777Y | Missense Mutation (SNP) | VAF 49/90 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV63285200, COSV63285206; called by muse, mutect2, varscan2
- LAMC2 | c.108G>C p.Q36H | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV51460222; called by muse, mutect2, varscan2
- NHS | c.902C>T p.P301L | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200313691, COSV101196623; called by muse, mutect2, varscan2
- NKX2-2 | c.473G>A p.R158H | Missense Mutation (SNP) | VAF 37/117 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1298869144, COSV65820463; called by muse, mutect2, varscan2
- NSDHL | c.202G>C p.D68H | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV64745476; called by muse, mutect2, varscan2
- PIK3CG | c.167C>T p.T56M | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs1315748037, COSV63254488; called by muse, mutect2, varscan2
- PKD2L1 | c.1984C>T p.R662* | Nonsense Mutation (SNP) | VAF 26/112 reads (23%) | catalogued as rs745318706, COSV58399353; called by muse, mutect2, varscan2
- PKHD1 | c.7558C>A p.H2520N | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV61889506, COSV61897151, COSV61897818; called by muse, mutect2, varscan2
- PKHD1 | c.5959G>A p.A1987T | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.41); PolyPhen benign (0.102); catalogued as rs375949362; called by muse, mutect2, varscan2
- PRPF6 | c.1768C>T p.R590W | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV99412048; called by muse, mutect2, varscan2
- PUDP | c.356C>T p.S119L | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.08); catalogued as rs1353961122, COSV66905503; called by muse, mutect2
- RADX | c.2158G>A p.D720N | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV65320280; called by muse, mutect2, varscan2
- SCARF1 | c.1151C>G p.S384C | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV53961739; called by muse, mutect2, varscan2
- SERPINB11 | c.953C>T p.S318F | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66957931; called by muse, mutect2, varscan2
- TBX22 | c.371C>T p.S124F | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64788150; called by muse, mutect2, varscan2
- TP73 | c.668C>T p.S223L | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.333); catalogued as rs753917723, COSV60706664; called by muse, mutect2, varscan2
- TTC30A | c.304G>A p.A102T | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV53710852; called by muse, mutect2, varscan2
- USP6NL | c.90G>C p.E30D | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as rs764335345, COSV53216347; called by muse, mutect2, varscan2
- CXCL1 | c.226_238del p.X76_splice | Splice Site (DEL) | VAF 5/65 reads (8%) | called by mutect2, pindel
- POLM | c.1081del p.L361Cfs*55 | Frame Shift Del (DEL) | VAF 38/111 reads (34%) | called by mutect2, pindel, varscan2
- ABCG8 | c.1299C>T p.F433= | Silent (SNP) | VAF 27/75 reads (36%) | catalogued as rs1215081986; called by muse, mutect2, varscan2
- AMBRA1 | c.3252G>A p.L1084= (on ENST00000458649 / NM_001367468.1; = p.L994= on NM_017749.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 21/63 reads (33%) | catalogued as COSV54063638; called by muse, mutect2, varscan2
- CTSW | c.651C>T p.F217= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as COSV57173402; called by muse, mutect2, varscan2
- DICER1 | c.2316G>A p.V772= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as rs878855250, COSV58629358; ClinVar: likely benign; called by muse, mutect2, varscan2
- DMRT1 | c.909C>T p.S303= | Silent (SNP) | VAF 16/63 reads (25%) | catalogued as rs534737562, COSV66524957; called by muse, mutect2, varscan2
- FAM47A | c.631C>T p.L211= | Silent (SNP) | VAF 32/139 reads (23%) | catalogued as COSV100650062, COSV60500224; called by muse, mutect2, varscan2
- FEN1 | c.468C>G p.P156= | Silent (SNP) | VAF 12/26 reads (46%) | catalogued as COSV57251584; called by muse, mutect2, varscan2
- GLMP | c.549G>A p.R183= | Silent (SNP) | VAF 23/105 reads (22%) | catalogued as COSV55294987, COSV55298161; called by muse, mutect2, varscan2
- LONP2 | c.2385G>A p.L795= | Silent (SNP) | VAF 20/38 reads (53%) | catalogued as COSV53526862; called by muse, mutect2, varscan2
- MAML2 | c.930C>T p.F310= | Silent (SNP) | VAF 40/107 reads (37%) | catalogued as COSV73264945; called by muse, mutect2, varscan2
- MTSS1 | c.168C>T p.D56= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as rs986703261, COSV61497439; called by muse, mutect2, varscan2
- OR2G2 | c.822C>A p.G274= | Silent (SNP) | VAF 45/162 reads (28%) | catalogued as rs759070345, COSV60742534; called by muse, mutect2, varscan2
- PCDHA1 | c.63C>T p.L21= | Silent (SNP) | VAF 26/81 reads (32%) | catalogued as COSV65377305; called by muse, mutect2, varscan2
- POU6F2 | c.1224C>T p.P408= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as rs1210208458, COSV68868487; called by muse, mutect2, varscan2
- SFTPC | c.546C>T p.G182= | Silent (SNP) | VAF 13/45 reads (29%) | catalogued as rs1245108260, COSV59346352; called by muse, mutect2, varscan2
- SIPA1L3 | c.1989G>A p.L663= | Silent (SNP) | VAF 14/31 reads (45%) | catalogued as COSV99728909; called by muse, mutect2, varscan2
- SLC22A10 | c.1470G>T p.T490= | Silent (SNP) | VAF 20/83 reads (24%) | catalogued as rs910284800, COSV60423844; called by muse, mutect2, varscan2
- SLITRK1 | c.1110G>A p.L370= | Silent (SNP) | VAF 3/11 reads (27%) | catalogued as COSV65677883; called by muse, mutect2
- TLN1 | c.3294G>A p.V1098= | Silent (SNP) | VAF 29/88 reads (33%) | catalogued as COSV59212326; called by muse, mutect2, varscan2
- TRPM1 | c.3834C>T p.N1278= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as rs374471543, CM097764; called by muse, mutect2, varscan2
- TUBB7P | n.229C>T | RNA (SNP) | VAF 25/75 reads (33%) | catalogued as rs1158074924; called by muse, mutect2, varscan2
